Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3MV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3MV-06A (Metastatic).

ICD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue, leg C49.2

DIAGNOSIS

Patient ID -

1/7/12

lw

(A) RIGHT MEDIAL LEG, SKIN ELLIPSE:

METASTATIC MELANOMA INVOLVING SUBCUTANEOUS SOFT TISSUE, PRESENT LESS THAN 1.1 MM

FROM INKED TISSUE EDGE. (SEE COMMENT)

TUMOR SIZE: 30 x 20 x 20 MM (PER GROSS DESCRIPTION).

Tumor borders focally infiltrative.

Overlying skin and subcutaneous tissue with scar, present at inked peripheral tissue edges.

COMMENT

(A) The tumor cells demonstrate similar morphology to the patient's known melanoma of the right lower leg (see case Focal tumor necrosis is seen. At the request of the clinician (per protocol), an immunohistochemical study is performed here (on A1) and shows that the tumor cells are diffusely and strongly positive with a pan-melanocytic cocktail (HMB45, anti-MART1, and anti-tyrosinase). These findings support the above diagnosis.

Source: NCI Genomic Data Commons file 0918b050-15ef-4669-8351-029826565281 (TCGA-D3-A3MV.89056039-2FD8-4F96-9977-753DC4C4FE3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).